Somatic mutation profile of tumor specimen TARGET-10-PATJBC-09A (aliquot TARGET-10-PATJBC-09A-01D) from TARGET case TARGET-10-PATJBC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,948 days).
Specimen TARGET-10-PATJBC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f56f059-4ee1-4eb8-a3ba-d0699e53960f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATJBC-10A (Blood Derived Normal), aliquot TARGET-10-PATJBC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96586f13-454c-4ec4-a451-b3ec18699a66

The open-access MAF lists 25 somatic variants for this specimen: 22 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 2, In Frame Ins 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1901A>G p.D634G (on ENST00000288602 / NM_001374244.1; = p.D594G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs121913338, COSV56065695, COSV56224199, COSV56283955; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 25/47 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCL11B | c.1339C>T p.R447C (on ENST00000357195 / NM_001282237.2; = p.R376C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61734668; called by muse, mutect2, varscan2
- C8orf48 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); catalogued as rs780348430, COSV52046638; called by muse, mutect2, varscan2
- CDHR1 | c.2431G>A p.V811M | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs764500651, COSV60560815; called by muse, mutect2, varscan2
- CUL7 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54814586; called by muse, mutect2, varscan2
- IL27 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1401799029, COSV100112366, COSV60489591; called by muse, mutect2, varscan2
- MTA3 | c.1331G>T p.R444L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.386); catalogued as rs76558479, COSV63196834, COSV63196870; called by muse, mutect2, varscan2
- MYH1 | c.1360C>A p.Q454K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.157); catalogued as COSV56845788; called by muse, mutect2, varscan2
- NBEAL1 | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as rs1177108907, COSV71374014; called by muse, mutect2, varscan2
- NOTCH1 | c.5161G>A p.V1721M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53039416; called by muse, mutect2, varscan2
- NOTCH1 | c.4222_4223insCCC p.E1408delinsAQ | In Frame Ins (INS) | VAF 6/68 reads (9%) | catalogued as COSV53039427; called by mutect2, pindel, varscan2
- PPP1R7 | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV52144113; called by muse, mutect2, varscan2
- PTPN11 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs587778636, COSV61007370; ClinVar: not provided; called by muse, mutect2, varscan2
- SAMD3 | c.608C>G p.A203G | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV60775021, COSV60777176; called by muse, mutect2, varscan2
- STRN4 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs369933808; called by muse, mutect2, varscan2
- TRPC4 | c.2437G>A p.E813K (on ENST00000379705 / NM_016179.4; = p.E818K on NM_003306.3) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.031); catalogued as COSV58995211; called by muse, varscan2
- WT1 | c.1337G>C p.R446P | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.155); catalogued as rs1037084691, CM148987, COSV60067835, COSV60069216, COSV60071337, COSV60072267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WT1 | c.1101dup p.R368Tfs*5 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | catalogued as COSV100189346, COSV60065589, COSV60066153, COSV60066283, COSV60067539, COSV60069909, COSV60077657, COSV60077667, COSV60077683, COSV60078403, COSV60079676, COSV60084998, COSV60085351; called by mutect2, varscan2
- AC004593.2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- SKOR2 | c.209C>G p.T70S | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMARCA4 | c.2936_2938dup p.R979dup | In Frame Ins (INS) | VAF 18/31 reads (58%) | called by mutect2, varscan2
- SLC28A3 | c.1626C>T p.N542= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs147965649; called by muse, mutect2, varscan2
- TTC24 | c.678C>G p.A226= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs1015357111; called by muse, mutect2, varscan2
- PRMT8 | c.418-81G>A | Intron (SNP) | VAF 21/43 reads (49%) | catalogued as rs1156944132; called by muse, mutect2, varscan2
